Somatic mutation profile of tumor specimen TCGA-3B-A9HU-01A (aliquot TCGA-3B-A9HU-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9HU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 53.9 years (19,669 days).
Specimen TCGA-3B-A9HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6e9cac7-b014-44c8-941d-f1ffc6ad4f6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HU-10A (Blood Derived Normal), aliquot TCGA-3B-A9HU-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33d5c035-f841-40c7-8a7a-95ae5f26ec72

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 21, Silent 12, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 20/31 reads (65%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADAM11 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99567531; called by muse, mutect2, varscan2
- ADGRF4 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.938); catalogued as COSV99348496; called by muse, mutect2
- ANAPC5 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV55843525, COSV99946278; called by mutect2, varscan2
- AP5Z1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100804160; called by muse, mutect2, varscan2
- ASXL2 | c.2273C>G p.T758S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as COSV99711328; called by muse, mutect2
- CCDC65 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV99908093; called by muse, mutect2
- CHST1 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as rs1439004278, COSV100346285; called by muse, mutect2, varscan2
- CLMN | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV54182946; called by muse, mutect2, varscan2
- COL5A3 | c.3735G>C p.K1245N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV99319048; called by muse, mutect2, varscan2
- DAPP1 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.215); catalogued as COSV99596918; called by muse, mutect2
- DNAH7 | c.8917T>C p.F2973L | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415635; called by muse, mutect2, varscan2
- LTC4S | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99482246; called by muse, mutect2, varscan2
- MAPK8IP3 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV51721024; called by muse, mutect2, varscan2
- MYH10 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345433; called by muse, mutect2, varscan2
- RAVER1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99349104; called by muse, mutect2, varscan2
- RC3H2 | c.1547G>T p.R516I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100605692; called by muse, mutect2, varscan2
- RNF125 | c.695C>A p.T232K | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV99470535; called by muse, mutect2, varscan2
- SEMA3A | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs150205475, COSV99546966; called by muse, mutect2, varscan2
- SIDT2 | c.539A>C p.E180A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); catalogued as COSV99637831; called by muse, mutect2, varscan2
- SRGAP2 | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99832918; called by muse, mutect2, varscan2
- TRIM58 | c.170G>C p.C57S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63570615, COSV63571641; called by muse, mutect2, varscan2
- ADGRG2 | c.2621del p.F874Sfs*42 (on ENST00000379869 / NM_001079858.3; = p.F871Sfs*42 on NM_005756.4) | Frame Shift Del (DEL) | VAF 67/393 reads (17%) | called by mutect2, pindel, varscan2
- DNAH8 | c.13173G>T p.T4391= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs776969419, COSV100545788, COSV59438222; called by muse, mutect2, varscan2
- DNAJC5B | c.37C>T p.L13= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99395471; called by muse, mutect2, varscan2
- DSCAM | c.5937G>C p.L1979= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV101260423; called by muse, mutect2, varscan2
- FLNA | c.2838C>T p.G946= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs782612987, COSV100774799; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR78 | c.804C>T p.F268= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs772135205, COSV101223991; called by muse, mutect2, varscan2
- ICAM5 | c.132C>T p.F44= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs1308676347, COSV99320899; called by muse, mutect2, varscan2
- KIF4B | c.2247T>C p.N749= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV70527547; called by muse, mutect2, varscan2
- MARCO | c.948A>G p.G316= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100503570; called by muse, mutect2
- MECP2 | c.537C>A p.P179= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV57656187; called by muse, mutect2
- OR13D1 | c.345T>A p.I115= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100598700; called by muse, mutect2, varscan2
- PRICKLE3 | c.849T>C p.A283= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV100889924; called by muse, mutect2, varscan2
- SNAP91 | c.522A>G p.Q174= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99535487; called by muse, mutect2, varscan2
